Somatic mutation profile of tumor specimen MMRF_1797_1_BM_CD138pos (aliquot MMRF_1797_1_BM_CD138pos_T1_KBS5U_K11313) from MMRF case MMRF_1797, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.6 years (23,580 days).
Specimen MMRF_1797_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 928e421c-e8cf-495e-88d8-55ccc2f66431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1797_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1797_1_PB_WBC_C2_KBS5U_K11314; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8b1b3bf-50d0-450d-a8ce-a2e510c408b1

The open-access MAF lists 71 somatic variants for this specimen: 36 protein-altering or splice-affecting, 4 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 15, Intron 11, Silent 4, 5'UTR 3, Splice Site 2, Nonsense Mutation 1, In Frame Del 1, RNA 1, In Frame Ins 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 36/85 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- ATP9A | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs267605994, COSV58764247; called by muse, mutect2, varscan2
- CYP26B1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 148/282 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1348778460, COSV99134857; called by muse, mutect2, varscan2
- ELAC2 | c.1305-2A>G p.X435_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as rs779254943; called by muse, mutect2, varscan2
- H1-4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs576653028, COSV56800056, COSV56800948; called by muse, mutect2, varscan2
- IGHV2-70 | c.308T>G p.M103R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs534782395; called by mutect2, varscan2
- IGHV2-70 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs567922038; called by muse, varscan2
- IGLV3-25 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs145801212; called by muse, varscan2
- KCNG2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as rs1280106577, COSV60267436; called by muse, mutect2, varscan2
- LAMA5 | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs751534590; called by muse, mutect2, varscan2
- NOS2 | c.2615A>G p.K872R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs1252816961; called by muse, mutect2, varscan2
- OAS3 | c.1375-2A>G p.X459_splice | Splice Site (SNP) | VAF 84/170 reads (49%) | catalogued as rs1565977091; called by muse, mutect2, varscan2
- POT1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62934334; called by muse, mutect2
- RACGAP1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV56700779; called by muse, mutect2, varscan2
- SOX13 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1395278260; called by muse, mutect2, varscan2
- UBASH3A | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as rs141628178, COSV99369544; called by muse, mutect2, varscan2
- UGT2B10 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776194391; called by muse, mutect2, varscan2
- WDR90 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747006630; called by muse, mutect2, varscan2
- WNK4 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1452646256; called by muse, mutect2, varscan2
- BCHE | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP170 | c.2818A>G p.T940A | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM50A | c.896del p.D299Vfs*10 | Frame Shift Del (DEL) | VAF 38/84 reads (45%) | called by mutect2, pindel, varscan2
- HEATR6 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.089); called by muse, mutect2
- HNRNPU | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGHV1-58 | c.348_349insAGTTTACTCGCG p.A116_A117insSLLA | In Frame Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- LOX | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC6 | c.438T>A p.D146E | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKNOX2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2
- PRKCD | c.1911_1925del p.F637_A642delinsL | In Frame Del (DEL) | VAF 172/312 reads (55%) | called by mutect2, varscan2
- RC3H2 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RGS18 | c.698T>A p.I233N | Missense Mutation (SNP) | VAF 233/517 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SIPA1L1 | c.4369G>T p.A1457S | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC22A31 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SOX11 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 42/62 reads (68%) | called by muse, mutect2, varscan2
- SYCP1 | c.1352A>G p.K451R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2
- ZNF880 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC33 | c.183G>T p.V61= | Silent (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- DOCK6 | c.4893C>G p.L1631= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs745449252; called by muse, mutect2, varscan2
- PXDNL | c.2277C>T p.D759= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs199714889, COSV62492887; called by muse, mutect2, varscan2
- USP48 | c.1740T>C p.N580= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- AL450336.1 | n.96G>C | RNA (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- BDNF | c.-21-848G>T | Intron (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- C12orf65 | c.-1T>G | 5'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- C4orf17 | c.880+639A>G | Intron (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- CBX5 | c.*2090A>G | 3'UTR (SNP) | VAF 62/113 reads (55%) | catalogued as rs553561438; called by muse, mutect2, varscan2
- CDH10 | c.*413del | 3'UTR (DEL) | VAF 55/132 reads (42%) | catalogued as rs902371308; called by mutect2, pindel, varscan2
- CFTR | c.*1119T>C | 3'UTR (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- DHODH | c.*98A>G | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- DLGAP1 | c.1965+1509G>A | Intron (SNP) | VAF 15/41 reads (37%) | catalogued as rs1476864520; called by muse, mutect2, varscan2
- GPATCH2 | c.1167-154T>G | Intron (SNP) | VAF 51/60 reads (85%) | called by muse, mutect2, varscan2
- H3C12 | c.-2C>G | 5'UTR (SNP) | VAF 30/60 reads (50%) | catalogued as rs754281537; called by muse, mutect2, varscan2
- LGALS9 | chr17:27630060 C>T | 5'Flank (SNP) | VAF 36/73 reads (49%) | catalogued as rs1227757270; called by muse, mutect2, varscan2
- NLGN2 | c.*266_*273del | 3'UTR (DEL) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- NUB1 | c.872+93del | Intron (DEL) | VAF 55/126 reads (44%) | called by mutect2, pindel, varscan2
- OAT | c.521-50T>C | Intron (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- OGA | c.*719T>A | 3'UTR (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67597T>A | Intron (SNP) | VAF 87/208 reads (42%) | called by muse, mutect2, varscan2
- PHKG2 | c.*2184T>C | 3'UTR (SNP) | VAF 64/158 reads (41%) | catalogued as rs191838893; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-86180C>T | Intron (SNP) | VAF 49/98 reads (50%) | catalogued as rs151268541; called by muse, mutect2, varscan2
- SLAMF1 | c.*570A>G | 3'UTR (SNP) | VAF 82/193 reads (42%) | called by muse, mutect2, varscan2
- SMIM9 | c.-66A>C | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- SPTSSA | c.*767A>C | 3'UTR (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- TBX18 | c.*238C>T | 3'UTR (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- TMPO | c.*636G>A | 3'UTR (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- TP53RK | c.*1065G>C | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- TRAK2 | c.690+51C>A | Intron (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- VPS37C | c.*1077G>T | 3'UTR (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- VWF | c.55+18T>A | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- WNT2B | c.*4050C>A | 3'UTR (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2629G>A | Intron (SNP) | VAF 49/95 reads (52%) | catalogued as COSV62598263; called by muse, mutect2, varscan2
- ZNF488 | c.*1436C>T | 3'UTR (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
